Gene-level copy-number profile of tumor specimen ALCH-B36B-TTP1-A from ALCHEMIST case ALCH-B36B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,946 days).
Specimen ALCH-B36B-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4d0892c5-5889-4886-b23b-15dd9117a9f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36B-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/20fc4011-7169-4b6c-9dcc-3c16f6d947b2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 13; copy number 2: 3,458; copy number 3: 6,210; copy number 4: 46,201; copy number 5: 2,586; copy number 6: 83; copy number 7: 146; copy number 8: 50; copy number 9: 42; copy number 10: 2; copy number 11: 58; copy number 12: 26; copy number 15: 1; copy number 22: 2; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 132 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,760,617–155,854,456, 4 genes, copy number 11–12: AC104472.2, C3orf33, AC104472.3, SLC33A1.
- chr3:156,671,862–156,714,928, 3 genes, copy number 9: TIPARP-AS1, TIPARP, METTL15P1.
- chr3:160,256,986–160,399,880, 2 genes, copy number 9 (within-gene range 8–9): IFT80, RPL35AP10.
- chr3:160,404,588–160,404,825, 2 genes, copy number 9 (within-gene range 8–9): MIR15B, MIR16-2.
- chr3:160,696,929–161,448,242, 12 genes, copy number 9: SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42.
- chr3:161,816,909–165,846,519, 18 genes, copy number 9–11: AC131211.1, TOMM22P6, AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE.
- chr3:167,956,311–169,998,373, 38 genes, copy number 9–12: AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1.
- chr3:170,086,732–170,181,749, 2 genes, copy number 9: PHC3, RNU6-315P.
- chr3:172,505,508–172,604,006, 4 genes, copy number 9–11: TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr7:74,906,673–74,913,310, 1 gene, copy number 26: SPDYE12P.
- chr11:86,649–207,428, 8 genes, copy number 11 (within-gene range 3–11): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1.
- chr11:298,200–299,526, 1 gene, copy number 9: IFITM5.
- chr14:36,213,200–36,235,608, 2 genes, copy number 10: AL162511.1, RN7SKP21.
- chr16:4,257,186–4,273,075, 1 gene, copy number 9: TFAP4.
- chr16:4,608,883–4,615,027, 1 gene, copy number 15: UBALD1.
- chr16:32,199,902–32,202,822, 1 gene, copy number 9: ABHD17AP8.
- chr16:32,356,981–32,380,049, 2 genes, copy number 22: AC133548.1, ACTR3BP3.
- chr16:32,869,985–32,888,874, 3 genes, copy number 11: BCAP31P2, SLC6A10P, AC142086.1.
- chr21:7,744,962–8,603,984, 27 genes, copy number 11: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
